Somatic mutation profile of tumor specimen TCGA-BP-4962-01A (aliquot TCGA-BP-4962-01A-01D-1462-08) from TCGA case TCGA-BP-4962, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 58.2 years (21,255 days).
Specimen TCGA-BP-4962-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee4b4d42-584d-42f8-b7a9-ada8aef00d42.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-4962-11A (Solid Tissue Normal), aliquot TCGA-BP-4962-11A-01D-1462-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49895aeb-26bc-4369-9f8e-9604e6e151a1

The open-access MAF lists 43 somatic variants for this specimen: 39 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 3, Frame Shift Ins 2, Frame Shift Del 2, Translation Start Site 1, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAN | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1162747201, COSV61357880; called by muse, mutect2, varscan2
- ADCY8 | c.2105A>G p.H702R | Missense Mutation (SNP) | VAF 15/252 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as COSV53901133; called by muse, mutect2
- BAP1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.255); catalogued as COSV56232191, COSV56233932; called by muse, mutect2, varscan2
- CCDC88B | c.349C>T p.P117S | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs750187928, COSV57265375; called by muse, mutect2, varscan2
- CD163 | c.1343C>G p.S448C | Missense Mutation (SNP) | VAF 13/378 reads (3%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV100776091, COSV63133773; called by muse, mutect2
- CHRD | c.1841T>G p.L614R | Missense Mutation (SNP) | VAF 38/216 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52606374; called by muse, varscan2
- CLASP1 | c.563T>C p.I188T | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV55317998; called by muse, mutect2, varscan2
- CLUH | c.227T>A p.V76E (on ENST00000435359; = p.V114E on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as COSV70928217; called by muse, mutect2, varscan2
- DBH | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55040152; called by muse, mutect2, varscan2
- ECSIT | c.851C>A p.P284H | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52938860; called by muse, mutect2, varscan2
- ERCC1 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as rs1157986827, COSV50003875; called by muse, mutect2, varscan2
- FECH | c.953C>A p.S318Y | Missense Mutation (SNP) | VAF 26/308 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as CM102096, COSV50490458; called by muse, mutect2
- GRIK1 | c.784T>A p.L262I | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.421); catalogued as COSV58713552; called by muse, mutect2, varscan2
- HMGCR | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 14/484 reads (3%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.942); catalogued as COSV55314952; called by muse, mutect2
- LCE1A | c.88C>T p.P30S | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated, low confidence (0.89); PolyPhen possibly damaging (0.632); catalogued as COSV58726699; called by muse, mutect2
- NCDN | c.694G>C p.A232P | Missense Mutation (SNP) | VAF 27/117 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV57843499; called by muse, mutect2, varscan2
- NIPAL4 | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs199652326, COSV57425088; called by muse, mutect2, varscan2
- NONO | c.269T>G p.M90R | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as COSV52136432; called by muse, mutect2, varscan2
- PTPRM | c.2635G>A p.A879T | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59845195; called by muse, mutect2
- SEMA3A | c.2048G>A p.G683E | Missense Mutation (SNP) | VAF 76/307 reads (25%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV54864838; called by muse, mutect2, varscan2
- SIDT2 | c.425C>A p.T142N | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); catalogued as COSV54056078; called by muse, mutect2
- SLC26A11 | c.566A>G p.H189R | Missense Mutation (SNP) | VAF 31/181 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as COSV63279119; called by muse, mutect2, varscan2
- SLC3A1 | c.2040A>G p.I680M | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as COSV53215761; called by muse, mutect2
- SMARCA2 | c.1289A>T p.E430V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61805572; called by muse, mutect2, varscan2
- SOX5 | c.925G>A p.G309R | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV58622998; called by muse, mutect2, varscan2
- SPEF2 | c.3899A>C p.K1300T | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.32); PolyPhen benign (0.286); catalogued as COSV61545900; called by muse, mutect2, varscan2
- SPINK5 | c.1381C>A p.P461T | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56250723; called by muse, mutect2, varscan2
- SPINK5 | c.1382C>A p.P461Q | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56250760; called by muse, mutect2, varscan2
- SYNJ1 | c.3934C>T p.Q1312* | Nonsense Mutation (SNP) | VAF 50/343 reads (15%) | catalogued as COSV59144750; called by muse, mutect2, varscan2
- TANC1 | c.2306C>G p.T769R | Missense Mutation (SNP) | VAF 74/433 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as rs759945824, COSV55085103; called by muse, mutect2, varscan2
- TFR2 | c.1300G>T p.D434Y | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs887907860, COSV56153515; called by muse, mutect2
- TTN | c.58892A>G p.D19631G (on ENST00000591111; = p.D12207G on NM_003319.4) | Missense Mutation (SNP) | VAF 11/34 reads (32%) | PolyPhen benign (0); catalogued as COSV59949313; called by muse, mutect2, varscan2
- VHL | c.404dup p.L135Ffs*9 | Frame Shift Ins (INS) | VAF 73/310 reads (24%) | catalogued as COSV56542630; called by mutect2, pindel, varscan2
- DUOX1 | c.2492G>A p.G831D | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2
- MGA | c.786del p.L263* | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel, varscan2
- MYH14 | c.5467G>A p.A1823T | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.309); called by muse, mutect2
- MYH14 | c.5468C>T p.A1823V | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.568); called by muse, mutect2
- SALL1 | c.3417dup p.G1140Wfs*35 | Frame Shift Ins (INS) | VAF 16/85 reads (19%) | called by mutect2, pindel, varscan2
- ZNF208 | c.3288_3301del p.W1096Cfs*4 | Frame Shift Del (DEL) | VAF 33/263 reads (13%) | called by mutect2, pindel, varscan2
- ARL11 | c.258C>T p.Y86= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as rs377295532; called by muse, mutect2, varscan2
- NSUN2 | c.1104G>A p.T368= | Silent (SNP) | VAF 15/337 reads (4%) | catalogued as rs1395934240, COSV52953196; called by muse, mutect2
- SLC45A1 | c.1383C>T p.D461= | Silent (SNP) | VAF 30/179 reads (17%) | catalogued as rs954614646, COSV57093889; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73820712 A>G | 3'Flank (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
